Somatic mutation profile of tumor specimen TARGET-10-PARJWB-09A (aliquot TARGET-10-PARJWB-09A-01D) from TARGET case TARGET-10-PARJWB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,945 days).
Specimen TARGET-10-PARJWB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ebeca6e-978c-474a-8317-8116b7995ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJWB-14A (Bone Marrow Normal), aliquot TARGET-10-PARJWB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0c6e972-a47d-4767-b7bc-4edd7585f527

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- P3R3URF-PIK3R3 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 35/71 reads (49%) | PolyPhen benign (0); catalogued as rs1221837671; called by muse, mutect2, varscan2
- PRX | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs536876712, COSV52533755; called by muse, mutect2, varscan2
- CLASP1 | c.4037C>G p.T1346S | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- USP9X | c.6419del p.P2140Lfs*11 | Frame Shift Del (DEL) | VAF 79/289 reads (27%) | called by mutect2, pindel, varscan2
- SUMF2 | c.593-20C>T | Intron (SNP) | VAF 87/193 reads (45%) | called by muse, mutect2, varscan2
